Somatic mutation profile of tumor specimen 49f55bd6-a89a-4d18-b732-139c3d (aliquot 49f55bd6-a89a-4d18-b732-139c3d_D6) from CPTAC case 03BR010, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.4 years (28,652 days).
Specimen 49f55bd6-a89a-4d18-b732-139c3d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d4ac3d0-751b-4ff2-8d41-0e69120033dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 04fa7dba-53a4-4696-94e4-75efc5 (Blood Derived Normal), aliquot 04fa7dba-53a4-4696-94e4-75efc5_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88cd5b2e-1988-43d2-a49e-a7d6056406b8

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 4, Intron 3, Nonsense Mutation 2, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 92/220 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 287/365 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.6230G>A p.R2077H (on ENST00000367573 / NM_001205293.3; = p.R2034H on NM_000721.4) | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs759720068, COSV62385287, COSV62397428; called by muse, mutect2, varscan2
- CBFB | c.10G>T p.V4F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51997162; called by muse, mutect2, varscan2
- CDH1 | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 159/249 reads (64%) | catalogued as COSV55733946; called by muse, mutect2, varscan2
- CYB561D1 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 109/270 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs368199735; called by muse, mutect2, varscan2
- DPEP2 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755590475, COSV52055998; called by muse, mutect2, varscan2
- GAL3ST1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 93/143 reads (65%) | SIFT tolerated (0.54); PolyPhen benign (0.17); catalogued as rs144400477; called by muse, mutect2, varscan2
- IMPG2 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 169/452 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs138218456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LEO1 | c.1929A>T p.E643D | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs898196359; called by muse, mutect2, varscan2
- LZTR1 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 116/195 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773016962, CM151192, COSV53147760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOS3 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1182280759, COSV52495793; called by muse, mutect2, varscan2
- OR11H6 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 200/468 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs561839930, COSV100209980; called by muse, mutect2, varscan2
- OR13G1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 129/494 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139468272, COSV62944006; called by muse, mutect2, varscan2
- PHEX | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs765067632; called by muse, mutect2, varscan2
- PSMD3 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs148147676; called by muse, mutect2, varscan2
- TCHP | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560664869, COSV57165120; called by muse, mutect2, varscan2
- ZNF503 | c.66_68del p.G27del | In Frame Del (DEL) | VAF 10/132 reads (8%) | catalogued as rs772844174; called by mutect2, pindel
- AHNAK | c.16961G>A p.G5654E | Missense Mutation (SNP) | VAF 73/338 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.7297G>C p.E2433Q | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- CALU | c.52T>G p.L18V | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL17A1 | c.3077G>A p.S1026N | Missense Mutation (SNP) | VAF 405/512 reads (79%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX42 | c.2303A>G p.N768S | Missense Mutation (SNP) | VAF 156/374 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLX5 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 157/391 reads (40%) | called by muse, mutect2, varscan2
- DPM3 | c.46_59del p.S16Pfs*46 (on ENST00000341298; = p.S46Pfs*46 on NM_018973.3) | Frame Shift Del (DEL) | VAF 108/458 reads (24%) | called by mutect2, pindel, varscan2
- EXOC5 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.066); called by muse, mutect2
- FBXO11 | c.2319A>G p.I773M (on ENST00000403359 / NM_001190274.2; = p.I689M on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIFAP3 | c.707T>A p.L236H | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PCSK5 | c.1428C>A p.I476= | Splice Region (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- PSMB3 | c.360C>A p.F120L | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PTK2 | c.2383_2384insT p.D795Vfs*42 | Frame Shift Ins (INS) | VAF 37/112 reads (33%) | called by mutect2, pindel, varscan2
- REPS2 | c.1413G>A p.M471I | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SMG1 | c.9861T>A p.N3287K | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.92); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USP1 | c.1645C>A p.L549I | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- ALDH9A1 | c.363C>A p.I121= | Silent (SNP) | VAF 160/269 reads (59%) | catalogued as COSV61341014; called by muse, mutect2, varscan2
- AMELX | c.498C>T p.P166= | Silent (SNP) | VAF 155/359 reads (43%) | called by muse, mutect2, varscan2
- PLSCR3 | c.129T>A p.P43= | Silent (SNP) | VAF 18/54 reads (33%) | called by mutect2, varscan2
- SLC6A3 | c.981G>A p.G327= | Silent (SNP) | VAF 219/574 reads (38%) | catalogued as rs1253197013; called by muse, mutect2, varscan2
- AC136759.1 | n.924A>G | RNA (SNP) | VAF 152/399 reads (38%) | called by muse, mutect2, varscan2
- CRELD1 | c.914-22C>G | Intron (SNP) | VAF 179/479 reads (37%) | called by muse, mutect2, varscan2
- KHSRP | c.2127+132G>T | Intron (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- POLR1H | chr6:30057420 C>T | 5'Flank (SNP) | VAF 104/257 reads (40%) | called by muse, mutect2, varscan2
- SH3TC1 | c.172+281C>T | Intron (SNP) | VAF 78/183 reads (43%) | called by muse, mutect2, varscan2
